Somatic mutation profile of tumor specimen TCGA-YL-A8SO-01B (aliquot TCGA-YL-A8SO-01B-31D-A377-08) from TCGA case TCGA-YL-A8SO, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.6 years (23,584 days).
Specimen TCGA-YL-A8SO-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96708eb9-e032-4b86-97c3-d0e0c235f486.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A8SO-10A (Blood Derived Normal), aliquot TCGA-YL-A8SO-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2c40317-5fca-4a26-b241-99b821c796cc

The open-access MAF lists 38 somatic variants for this specimen: 27 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 23, Silent 11, Nonsense Mutation 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 18/49 reads (37%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SPOP | c.391T>G p.W131G | Missense Mutation (SNP) | VAF 40/133 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as rs1057519968, COSV61652911, COSV61653817; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACO1 | c.1412T>C p.L471P | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59376973; called by mutect2, varscan2
- ADGRG4 | c.964T>A p.S322T | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99796509; called by muse, mutect2, varscan2
- BYSL | c.1300A>T p.I434F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV100026931; called by muse, mutect2
- CLEC4C | c.639A>G p.I213M | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs147980423; called by muse, mutect2
- COL4A4 | c.2261G>A p.G754D | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100307579; called by muse, mutect2, varscan2
- CYP8B1 | c.1124T>A p.L375Q | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.023); catalogued as COSV100296274; called by muse, mutect2, varscan2
- DNAH2 | c.5085A>C p.E1695D | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as COSV101209560; called by muse, mutect2
- DNAJB4 | c.445G>T p.V149L | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs1439976581, COSV100883486; called by muse, mutect2, varscan2
- EPM2A | c.536A>T p.K179I | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV100837615; called by muse, mutect2, varscan2
- G3BP2 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV100693001; called by muse, mutect2
- HSD3B1 | c.762C>A p.Y254* | Nonsense Mutation (SNP) | VAF 19/83 reads (23%) | catalogued as COSV52491143, COSV99348074; called by muse, mutect2, varscan2
- LRP1B | c.11362G>A p.G3788R | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as rs199649226, COSV67221081, COSV67275670; called by muse, mutect2, varscan2
- MAGEC1 | c.1267A>C p.I423L | Missense Mutation (SNP) | VAF 57/101 reads (56%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs199509682, COSV99596400; called by muse, mutect2, varscan2
- MSH3 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV54149357, COSV99435360; called by muse, mutect2, varscan2
- MUC16 | c.5314G>A p.E1772K | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as COSV101201332; called by muse, mutect2, varscan2
- OR1D2 | c.807G>T p.K269N | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as COSV100513959; called by muse, mutect2
- OTOF | c.4339G>A p.E1447K (on ENST00000272371 / NM_194248.3; = p.E680K on NM_004802.4) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs201493014, COSV55526072; called by muse, mutect2, varscan2
- PLCB4 | c.1648G>T p.A550S | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.063); catalogued as COSV53822727; called by muse, mutect2, varscan2
- PLCH1 | c.2567A>G p.N856S (on ENST00000340059 / NM_001130960.2; = p.N868S on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.171); catalogued as rs1348148794, COSV100398086; called by muse, mutect2, varscan2
- SPARCL1 | c.1669G>A p.V557I | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99215844; called by muse, mutect2, varscan2
- TAAR2 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.979); catalogued as COSV51579053; called by muse, mutect2
- TARS2 | c.803G>T p.G268V | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.171); catalogued as COSV100946087; called by muse, mutect2
- TRERF1 | c.1963C>T p.R655W | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142184147, COSV61668035; called by muse, mutect2
- KMT2A | c.7732del p.T2578Pfs*21 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel, varscan2
- PEX5 | c.1158_1159dup p.L387Yfs*2 (on ENST00000420616; = p.L379Yfs*2 on NM_000319.5) | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by mutect2, pindel
- ACTG1 | c.336C>T p.P112= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs532725688, COSV100112053; called by muse, mutect2, varscan2
- CATSPERD | c.1146C>G p.L382= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV100486958, COSV58465021; called by muse, mutect2, varscan2
- CCNA1 | c.1041T>C p.F347= | Silent (SNP) | VAF 31/132 reads (23%) | catalogued as rs1402771258, COSV99714841; called by muse, mutect2, varscan2
- KIR2DL1 | c.867C>T p.S289= | Silent (SNP) | VAF 12/123 reads (10%) | catalogued as rs2736416, COSV99383584, COSV99383745; called by muse, mutect2
- RAD21 | c.1758A>C p.R586= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV99815574; called by muse, mutect2, varscan2
- RUSC2 | c.1539G>A p.S513= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs762004806, COSV100770857; called by muse, mutect2, varscan2
- SIPA1L3 | c.2721G>A p.V907= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as COSV99730256; called by muse, mutect2
- SSX5 | c.219T>C p.N73= (on ENST00000347757 / NM_175723.1; = p.N114= on NM_021015.4) | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as rs1556925363, COSV100308880; called by muse, mutect2, varscan2
- TPR | c.1653A>G p.Q551= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs774989116, COSV100824233; called by muse, mutect2, varscan2
- TRMT61A | c.693G>A p.L231= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as COSV100149439; called by muse, mutect2, varscan2
- ZNF836 | c.2136T>C p.Y712= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV100441189; called by muse, mutect2, varscan2
